Somatic mutation profile of tumor specimen TCGA-DB-5279-01A (aliquot TCGA-DB-5279-01A-01D-1468-08) from TCGA case TCGA-DB-5279, project TCGA-LGG (Brain Lower Grade Glioma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Oligodendroglioma, NOS; Tissue or organ of origin: Cerebrum; Tumor grade: G2; Age at diagnosis: 60.0 years (21,908 days).
Specimen TCGA-DB-5279-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 88982793-4a43-467d-a7af-2e285688fb46.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-DB-5279-10A (Blood Derived Normal), aliquot TCGA-DB-5279-10A-01D-1468-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b45b57bb-fd41-4676-baf2-09270e7bba5e

The open-access MAF lists 49 somatic variants for this specimen: 32 protein-altering or splice-affecting, 15 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 27, Silent 15, Nonsense Mutation 4, Intron 1, Frame Shift Del 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- IDH1 | c.395G>A p.R132H | Missense Mutation (SNP) | VAF 68/144 reads (47%) | hotspot (GDC flag); SIFT deleterious, low confidence (0.01); PolyPhen benign (0.047); catalogued as rs121913500, CM1310533, COSV61615239, COSV61615420; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- PIK3R1 | c.1126G>A p.G376R (on ENST00000521381 / NM_181523.3; = p.G106R on NM_181504.4) | Missense Mutation (SNP) | VAF 43/114 reads (38%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1057519757, COSV57123316, COSV57132021, COSV57133701; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ABCC3 | c.1194C>G p.N398K | Missense Mutation (SNP) | VAF 10/127 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53331319; called by muse, mutect2
- ABHD15 | c.775G>A p.A259T | Missense Mutation (SNP) | VAF 16/25 reads (64%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs1438770098, COSV56196179; called by muse, mutect2
- CKS2 | c.20A>G p.Y7C | Missense Mutation (SNP) | VAF 16/38 reads (42%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.947); catalogued as rs1052637276, COSV58686724; called by muse, mutect2, varscan2
- ESRRG | c.551G>A p.R184H | Missense Mutation (SNP) | VAF 31/192 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs777160519, COSV100754101; called by muse, mutect2, varscan2
- FCRL5 | c.2243C>T p.P748L | Missense Mutation (SNP) | VAF 12/73 reads (16%) | SIFT deleterious (0.05); PolyPhen benign (0); catalogued as rs142943534; called by muse, mutect2, varscan2
- IRAG1 | c.2092G>A p.V698I | Missense Mutation (SNP) | VAF 31/70 reads (44%) | SIFT tolerated (0.24); PolyPhen probably damaging (0.909); catalogued as rs749109709, COSV70213298; called by muse, mutect2, varscan2
- JAK2 | c.2812C>T p.R938* | Nonsense Mutation (SNP) | VAF 112/134 reads (84%) | catalogued as rs750978665; called by muse, mutect2, varscan2
- KIAA1109 | c.7585G>A p.V2529M | Missense Mutation (SNP) | VAF 52/202 reads (26%) | SIFT tolerated (0.11); PolyPhen benign (0); catalogued as rs375646084; called by muse, mutect2, varscan2
- NEGR1 | c.68G>A p.S23N | Missense Mutation (SNP) | VAF 6/27 reads (22%) | SIFT tolerated (0.06); PolyPhen benign (0.076); catalogued as rs776574702, COSV100747038, COSV63248672; called by muse, mutect2, varscan2
- PAQR8 | c.290C>T p.A97V | Missense Mutation (SNP) | VAF 21/105 reads (20%) | SIFT tolerated (0.41); PolyPhen benign (0.026); catalogued as rs769610880, COSV62443298; called by muse, mutect2, varscan2
- PCDHB3 | c.1606C>T p.R536C | Missense Mutation (SNP) | VAF 21/89 reads (24%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.843); catalogued as rs1156469875, COSV50564255; called by muse, mutect2, varscan2
- REG3G | c.155A>G p.Y52C | Missense Mutation (SNP) | VAF 18/47 reads (38%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.654); catalogued as rs1415554116; called by muse, mutect2, varscan2
- SAFB2 | c.2578C>T p.R860C | Missense Mutation (SNP) | VAF 5/27 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.007); catalogued as rs376399865; called by muse, mutect2, varscan2
- SLA | c.745C>T p.R249* (on ENST00000338087 / NM_001045556.3; = p.R289* on NM_006748.4) | Nonsense Mutation (SNP) | VAF 70/293 reads (24%) | catalogued as COSV55074913, COSV55089813; called by muse, mutect2, varscan2
- TRPC4 | c.737G>A p.R246Q | Missense Mutation (SNP) | VAF 22/348 reads (6%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs200216544; called by muse, mutect2
- ZNF592 | c.706C>T p.R236* | Nonsense Mutation (SNP) | VAF 30/139 reads (22%) | catalogued as COSV100246051; called by muse, mutect2, varscan2
- CYP24A1 | c.907T>A p.C303S | Missense Mutation (SNP) | VAF 55/112 reads (49%) | SIFT tolerated (0.2); PolyPhen benign (0.385); called by muse, mutect2, varscan2
- FRY | c.6053C>G p.T2018S | Missense Mutation (SNP) | VAF 17/52 reads (33%) | SIFT tolerated (1); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- GRPEL2 | c.85C>T p.P29S | Missense Mutation (SNP) | VAF 32/155 reads (21%) | SIFT tolerated (0.56); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- HTR3A | c.371A>T p.E124V | Missense Mutation (SNP) | VAF 24/59 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- INSC | c.1445C>A p.A482D | Missense Mutation (SNP) | VAF 3/46 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); called by muse, mutect2
- LRCH3 | c.1094A>G p.N365S | Missense Mutation (SNP) | VAF 18/88 reads (20%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.817); called by muse, mutect2, varscan2
- MIPEP | c.1489A>G p.M497V | Missense Mutation (SNP) | VAF 61/269 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); called by muse, mutect2, varscan2
- NCF2 | c.500G>A p.W167* | Nonsense Mutation (SNP) | VAF 177/382 reads (46%) | called by muse, mutect2, varscan2
- NEDD9 | c.1105T>C p.S369P | Missense Mutation (SNP) | VAF 61/124 reads (49%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- NUP210L | c.2324C>T p.A775V | Missense Mutation (SNP) | VAF 108/336 reads (32%) | SIFT tolerated (0.23); PolyPhen benign (0.007); called by muse, varscan2
- SHOC2 | c.748C>A p.L250I | Missense Mutation (SNP) | VAF 10/110 reads (9%) | SIFT tolerated (0.28); PolyPhen possibly damaging (0.888); called by muse, mutect2
- TJP1 | c.1858G>A p.D620N | Missense Mutation (SNP) | VAF 50/159 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ZCCHC9 | c.671_674del p.K224Ifs*21 | Frame Shift Del (DEL) | VAF 167/490 reads (34%) | called by pindel, varscan2
- ZNF546 | c.1534C>G p.L512V | Missense Mutation (SNP) | VAF 43/60 reads (72%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- ATP8B3 | c.3424C>T p.L1142= | Silent (SNP) | VAF 4/20 reads (20%) | called by muse, mutect2, varscan2
- ENSA | c.162C>T p.L54= | Silent (SNP) | VAF 96/184 reads (52%) | catalogued as rs1263135891; called by muse, mutect2, varscan2
- GPX6 | c.630C>T p.D210= | Silent (SNP) | VAF 64/147 reads (44%) | called by muse, mutect2, varscan2
- ITGAL | c.3213C>T p.N1071= | Silent (SNP) | VAF 14/82 reads (17%) | catalogued as rs779359688; called by muse, mutect2
- LRRC7 | c.2667G>A p.P889= (on ENST00000651989 / NM_001370785.2; = p.P856= on NM_001330635.3 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 79/91 reads (87%) | catalogued as rs759651343, COSV50411916; called by muse, mutect2, varscan2
- MAG | c.1638C>T p.P546= | Silent (SNP) | VAF 14/16 reads (88%) | catalogued as COSV100728002; called by muse, mutect2, varscan2
- MAGEC1 | c.2739C>T p.D913= | Silent (SNP) | VAF 13/222 reads (6%) | catalogued as rs370841892, COSV99595087; called by muse, mutect2
- MCCC1 | c.1092A>G p.A364= | Silent (SNP) | VAF 92/221 reads (42%) | called by muse, mutect2, varscan2
- RBM6 | c.2457C>T p.P819= | Silent (SNP) | VAF 20/65 reads (31%) | catalogued as rs200245501; called by muse, mutect2, varscan2
- SIM1 | c.1302C>T p.C434= | Silent (SNP) | VAF 23/101 reads (23%) | called by muse, mutect2, varscan2
- SLC17A7 | c.1614G>A p.P538= | Silent (SNP) | VAF 10/19 reads (53%) | catalogued as rs546442351, COSV55546508; called by muse, mutect2, varscan2
- SPOPL | c.210G>A p.R70= | Silent (SNP) | VAF 36/202 reads (18%) | catalogued as rs369405867; called by muse, varscan2
- STMN3 | c.498C>T p.A166= | Silent (SNP) | VAF 5/10 reads (50%) | called by muse, mutect2
- SUMF1 | c.459C>T p.G153= | Silent (SNP) | VAF 112/278 reads (40%) | catalogued as rs148557574; called by muse, mutect2, varscan2
- TRPV3 | c.105C>T p.T35= | Silent (SNP) | VAF 33/68 reads (49%) | called by muse, mutect2, varscan2
- ITGA6 | c.3232-2219A>T | Intron (SNP) | VAF 20/118 reads (17%) | called by muse, mutect2, varscan2
- SNORD115-16 | n.81C>A | RNA (SNP) | VAF 81/320 reads (25%) | called by muse, mutect2, varscan2
